Somatic mutation profile of tumor specimen TCGA-HT-7902-01A (aliquot TCGA-HT-7902-01A-12D-2395-08) from TCGA case TCGA-HT-7902, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.4 years (11,118 days).
Specimen TCGA-HT-7902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2a2f8df-e859-450c-b289-6179dfb88882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7902-10A (Blood Derived Normal), aliquot TCGA-HT-7902-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee83e38e-0cd4-40d9-b2fa-ae740703dd86

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ANXA3 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV53716618; called by muse, mutect2
- ATRX | c.6080T>C p.L2027P | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64882217; called by muse, mutect2, varscan2
- CACNG3 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50080601; called by muse, mutect2
- ECEL1 | c.1331A>C p.Q444P | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV58814047; called by muse, mutect2
- GPRC5D | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs201926763, COSV57433357; called by muse, mutect2, varscan2
- HIVEP3 | c.5285G>A p.R1762H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403670515, COSV56012853; called by muse, mutect2, varscan2
- MS4A14 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV55731537; called by muse, mutect2, varscan2
- MUC16 | c.13958C>A p.T4653K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67488624; called by muse, mutect2
- NKX2-1 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV61390158; called by muse, mutect2, varscan2
- PAPPA2 | c.3104T>A p.L1035H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62809493; called by muse, mutect2
- PECR | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV54735682; called by muse, mutect2, varscan2
- PTPRG | c.2640C>G p.Y880* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV55659736; called by muse, mutect2, varscan2
- RNPEPL1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54373778; called by muse, mutect2, varscan2
- SMARCA1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as COSV64413498; called by muse, mutect2, varscan2
- TGM5 | c.726G>A p.W242* (on ENST00000220420 / NM_201631.4; = p.W160* on NM_004245.4) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV55011848; called by muse, mutect2, varscan2
- TIMM44 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54494280; called by muse, mutect2, varscan2
- USH2A | c.10364G>A p.S3455N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56423666; called by muse, mutect2, varscan2
- MYT1 | c.2065_2092del p.C689Pfs*17 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel
- ATAD2B | c.3306G>C p.R1102= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53204270; called by muse, mutect2, varscan2
- OR4C16 | c.150C>T p.S50= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as rs1196978816, COSV58941569, COSV58943979; called by muse, mutect2, varscan2
- TENM1 | c.6984C>T p.S2328= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV64440968; called by muse, mutect2
